Gene-level copy-number profile of specimen HCM-BROD-0724-C43-85M from HCMI case HCM-BROD-0724-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 74.4 years (27,189 days).
Specimen HCM-BROD-0724-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f7c0a794-c1f4-4a1c-b08e-a41093671d12.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0724-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/45e0b45c-d24e-4830-9135-31f73444a023

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 62; copy number 2: 2,829; copy number 3: 23,343; copy number 4: 12,699; copy number 5: 11,722; copy number 6: 4,110; copy number 7: 2,207; copy number 8: 275; copy number 9: 121; copy number 10: 48; copy number 11: 149; copy number 12: 231; copy number 13: 297; copy number 14: 100; copy number 15: 22; copy number 16: 115; copy number 17: 7; copy number 18: 27; copy number 24: 16; copy number 30: 5; copy number 35: 2; copy number 36: 4; copy number 38: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,629 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–143,760,669, 9 genes, copy number 7: AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1.
- chr6:6,901,022–6,918,715, 1 gene, copy number 7: AL158817.1.
- chr7:63,011,463–89,338,528, 499 genes, copy number 7–18 (broad region; genes not listed).
- chr7:91,264,433–93,361,123, 36 genes, copy number 7–13: FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50.
- chr7:93,591,573–97,972,985, 75 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr7:98,106,862–106,838,480, 266 genes, copy number 8–13 (broad region; genes not listed).
- chr7:107,044,705–114,693,772, 82 genes, copy number 8–18 (within-gene range 6–18) (broad region; genes not listed).
- chr7:114,922,359–119,179,149, 67 genes, copy number 9–17 (within-gene range 7–17) (broad region; genes not listed).
- chr7:120,005,976–120,750,337, 4 genes, copy number 9–10 (within-gene range 6–10): RNU1-29P, AC004946.1, AC004946.2, KCND2.
- chr7:126,378,970–135,317,752, 198 genes, copy number 9–18 (broad region; genes not listed).
- chr7:139,561,570–141,052,409, 29 genes, copy number 10–11: HIPK2, TBXAS1, PARP12, KDM7A, Y_RNA, KDM7A-DT, RNU6-797P, RNU1-58P, AC005377.1, PPP1R2P6, SLC37A3, RNA5SP247, RNA5SP248, RAB19, AC069335.1, MKRN1, DENND2A, Y_RNA, AC006452.1, RN7SL771P, ADCK2, NDUFB2, NDUFB2-AS1, BRAF, RNU6-85P, AC006006.1, CCT4P1, MRPS33, RNU4-74P.
- chr7:144,086,278–149,624,752, 83 genes, copy number 11–16 (broad region; genes not listed).
- chr7:152,749,079–159,233,377, 91 genes, copy number 8–16 (broad region; genes not listed).
- chr8:79,891,553–80,080,775, 4 genes, copy number 7 (within-gene range 6–7): AC036214.4, MRPS28, AC036214.3, AC036214.2.
- chr15:48,120,990–49,620,929, 39 genes, copy number 14–38: SLC24A5, MYEF2, CTXN2, SLC12A1, AC066612.1, AC066612.2, AC023355.1, Y_RNA, DUT, FBN1, AC022467.2, AC022467.1, AC084757.3, AC084757.4, CEP152, AC084757.1, AC084757.2, AC012379.1, AC012379.2, SHC4, EID1, AC091073.1, KRT8P24, SECISBP2L, Y_RNA, RN7SL577P, AC013452.2, COPS2, Y_RNA, GALK2, NDUFAF4P1, MIR4716, AC013452.1, RN7SL307P, FAM227B, AC022306.2, AC022306.3, AC022306.1, FGF7.
- chr15:84,186,752–85,330,334, 49 genes, copy number 14: CSPG4P11, GOLGA2P7, RN7SL331P, GOLGA6L4, UBE2Q2P8, AC243562.2, RN7SL417P, AC243562.1, DNM1P51, CSPG4P5, UBE2Q2P11, AC243562.3, Metazoa_SRP, UBE2Q2P12, AC048382.4, AC048382.3, GOLGA6L5P, AC048382.2, UBE2Q2P1, LINC00933, AC048382.5, ZSCAN2, AC048382.1, AC048382.6, SCAND2P, EGLN1P1, WDR73, Metazoa_SRP, NMB, SEC11A, AC115102.1, ZNF592, AC012291.2, ALPK3, AC012291.1, SLC28A1, AC087468.2, RNU6-339P, RNU6-796P, AC087468.1, PDE8A, AC044860.2, AC044860.1, NIFKP8, CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3.
- chr15:90,388,242–90,502,239, 1 gene, copy number 15 (within-gene range 3–15): IQGAP1.
- chr15:90,529,923–90,954,093, 19 genes, copy number 15 (within-gene range 4–15): CRTC3, AC103739.1, AC103739.2, CRTC3-AS1, AC103739.3, HSPE1P3, AC021422.1, LINC01585, BLM, SNORD18, AC124248.2, AC124248.1, RN7SL363P, FURIN, FES, MAN2A2, AC068831.3, HDDC3, UNC45A.
- chr17:50,050,349–50,287,855, 19 genes, copy number 7: PICART1, ITGA3, AC002401.4, PDK2, AC002401.3, AC002401.2, SAMD14, PPP1R9B, AC002401.1, AC015909.2, AC015909.3, SGCA, H1-9P, COL1A1, AC015909.1, AC015909.4, SUMO2P7, TMEM92, TMEM92-AS1.
- chr17:50,719,565–50,756,219, 1 gene, copy number 7 (within-gene range 6–7): LUC7L3.
- chr17:50,761,029–54,478,168, 40 genes, copy number 7: ANKRD40CL, MIR8059, AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4, AC005920.1, AC005920.3, SPAG9, AC005920.2, NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18, LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48, CA10, AC002090.1, LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3.
- chr17:55,264,960–77,728,559, 648 genes, copy number 7 (broad region; genes not listed).
- chr17:80,169,992–80,542,605, 17 genes, copy number 7: CARD14, AC087741.1, SGSH, SLC26A11, RNF213, AC124319.1, AC124319.2, AC124319.3, RNF213-AS1, ENDOV, MIR4730, AC120024.1, AC120024.4, NPTX1, AC120024.2, AC120024.3, RPL32P31.
- chr22:15,282,557–50,801,309, 1,352 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 62. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
